Somatic mutation profile of tumor specimen 0DQJIX from CCDI case PBCFGG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.6 years (3,875 days).
Specimen 0DQJIX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6141adc-d12f-423a-9545-ab7430d5c3fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQJIL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d44a08a-8fba-43dc-851d-c10b3cfc361b

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 244/419 reads (58%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 241/653 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AMD1 | c.783G>T p.Q261H | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.07); catalogued as COSV64388226; called by muse, mutect2
- COL22A1 | c.529G>C p.V177L | Missense Mutation (SNP) | VAF 63/983 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as COSV57339725; called by muse, mutect2
- DNAH2 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 48/484 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.243); catalogued as rs550356284, COSV50017329; called by muse, mutect2
- IMPG2 | c.2999A>T p.K1000I | Missense Mutation (SNP) | VAF 122/313 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1324055902; called by muse, mutect2, varscan2
- TCHH | c.4921C>T p.R1641C | Missense Mutation (SNP) | VAF 628/1111 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.454); catalogued as COSV64276853; called by muse, mutect2, varscan2
- CHD7 | c.6975A>C p.E2325D | Missense Mutation (SNP) | VAF 91/270 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- CUX1 | c.4206_4209del p.P1403Afs*81 | Frame Shift Del (DEL) | VAF 106/250 reads (42%) | called by mutect2, pindel, varscan2
- DCTPP1 | c.415del p.R139Afs*46 | Frame Shift Del (DEL) | VAF 106/286 reads (37%) | called by mutect2, pindel, varscan2
- HAS2 | c.1222_1224del p.L408del | In Frame Del (DEL) | VAF 65/515 reads (13%) | called by pindel, varscan2
- IFT52 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 146/391 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- SYNPR | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 219/533 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- GCOM1 | c.222T>C p.G74= | Silent (SNP) | VAF 58/351 reads (17%) | catalogued as COSV99985493; called by muse, mutect2, varscan2
- GNB1L | c.681C>A p.S227= | Silent (SNP) | VAF 170/409 reads (42%) | called by muse, mutect2, varscan2
- SRP68 | c.1440C>T p.S480= | Silent (SNP) | VAF 192/679 reads (28%) | catalogued as rs751426983; called by muse, mutect2, varscan2
